Somatic mutation profile of tumor specimen TCGA-BP-5004-01A (aliquot TCGA-BP-5004-01A-01D-1462-08) from TCGA case TCGA-BP-5004, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.1 years (19,383 days).
Specimen TCGA-BP-5004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ec65ce8-f2bd-4bcf-b651-1be8736b3680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5004-11A (Solid Tissue Normal), aliquot TCGA-BP-5004-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00e6ac99-0578-4aec-8188-7ef5f3ffe406

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Del 8, Silent 8, In Frame Del 3, Splice Site 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.4900C>T p.R1634C (on ENST00000447894 / NM_001366320.1; = p.R1632C on NM_001040000.3) | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as rs781720897, COSV60053577; called by muse, mutect2, varscan2
- BEND7 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61990750; called by muse, mutect2, varscan2
- CHAF1B | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58441299; called by muse, mutect2, varscan2
- COL5A1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs755546104, COSV65672891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEFB108B | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60822670; called by muse, mutect2, varscan2
- DHX29 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs751444845, COSV52421202; called by muse, mutect2, varscan2
- EEF1A2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV53207826; called by muse, mutect2, varscan2
- FADS2 | c.545A>C p.Y182S | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV53901456; called by muse, mutect2, varscan2
- GLI3 | c.2619C>A p.S873R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779193787, COSV67893809; called by muse, varscan2
- GNAT1 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.442); catalogued as COSV51698642; called by muse, mutect2, varscan2
- HMCES | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 71/265 reads (27%) | catalogued as COSV67300857; called by muse, varscan2
- KIF5C | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69173252; called by muse, mutect2, varscan2
- LILRA6 | c.129C>G p.S43R | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV54444714, COSV99557764; called by muse, mutect2, varscan2
- LRRC59 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815343; called by muse, mutect2, varscan2
- MEMO1 | c.446A>C p.D149A | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.239); catalogued as COSV54455884; called by muse, mutect2, varscan2
- MSRB1 | c.234G>C p.L78F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51908091, COSV99238540; called by muse, mutect2, varscan2
- MUC16 | c.24563C>T p.T8188I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as COSV67486763; called by muse, mutect2, varscan2
- MYO6 | c.1474-1G>C p.X492_splice | Splice Site (SNP) | VAF 32/149 reads (21%) | catalogued as COSV64120806; called by muse, mutect2, varscan2
- NAP1L2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1428399931, COSV65172680; called by muse, mutect2
- NUMB | c.310-2A>G p.X104_splice (on ENST00000355058; = p.X93_splice on NM_003744.5) | Splice Site (SNP) | VAF 25/60 reads (42%) | catalogued as COSV61831692; called by muse, mutect2, varscan2
- PCDHA10 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV56474455, COSV56477977; called by muse, mutect2, varscan2
- PRPF8 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV59266726; called by muse, mutect2, varscan2
- SH2D3C | c.2185del p.L729Sfs*10 (on ENST00000314830 / NM_170600.3; = p.L572Sfs*10 on NM_005489.4) | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as COSV100137660; called by mutect2, pindel, varscan2
- SYT11 | c.15del p.N6Ifs*27 | Frame Shift Del (DEL) | VAF 38/225 reads (17%) | catalogued as COSV55203437; called by mutect2, pindel, varscan2
- TLN2 | c.3629A>T p.D1210V | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60894274; called by muse, mutect2, varscan2
- TMEM255B | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 27/67 reads (40%) | catalogued as COSV64704672; called by muse, mutect2, varscan2
- TNNT3 | c.334G>A p.A112T (on ENST00000397301 / NM_001367846.1; = p.A101T on NM_006757.4) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV53489076; called by muse, mutect2, varscan2
- TNS1 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV50751149; called by muse, mutect2, varscan2
- TTC30A | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63102184; called by muse, mutect2, varscan2
- UNC119B | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 77/319 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV60866621; called by muse, mutect2, varscan2
- ZNF492 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 55/334 reads (16%) | catalogued as COSV71762313; called by muse, mutect2, varscan2
- ALDOA | c.468del p.G157Vfs*7 (on ENST00000642816 / NM_001243177.4; = p.G103Vfs*7 on NM_184041.5) | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.2427_2429del p.S809_L810delinsR | In Frame Del (DEL) | VAF 33/165 reads (20%) | called by mutect2, pindel, varscan2
- DST | c.3875_3885del p.L1292Qfs*9 (on ENST00000361203 / NM_001374722.1; = p.L966Qfs*9 on NM_001723.6) | Frame Shift Del (DEL) | VAF 21/123 reads (17%) | called by mutect2, pindel, varscan2
- NDUFC1 | c.159_161del p.F53del | In Frame Del (DEL) | VAF 22/82 reads (27%) | called by pindel, varscan2
- NYAP1 | c.820del p.E274Kfs*10 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- PPFIA1 | c.886_894del p.K296_E298del | In Frame Del (DEL) | VAF 31/162 reads (19%) | called by mutect2, pindel, varscan2
- RNASE3 | c.51del p.M19Wfs*27 | Frame Shift Del (DEL) | VAF 60/346 reads (17%) | called by mutect2, varscan2
- SFMBT1 | c.2447del p.I816Nfs*3 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.3384del p.E1130Kfs*14 | Frame Shift Del (DEL) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- CCDC146 | c.2178C>T p.D726= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV53553003, COSV99592548; called by muse, mutect2, varscan2
- DIP2B | c.4008T>C p.T1336= | Silent (SNP) | VAF 95/320 reads (30%) | catalogued as COSV56579723, COSV56590288; called by muse, mutect2, varscan2
- HEATR9 | c.987C>A p.V329= | Silent (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- HLA-C | c.531G>C p.A177= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs41560918; called by mutect2, varscan2
- RNF148 | c.609C>G p.A203= | Silent (SNP) | VAF 55/205 reads (27%) | catalogued as COSV57373896, COSV57380878; called by muse, mutect2, varscan2
- SERPINB4 | c.21C>G p.A7= | Silent (SNP) | VAF 82/387 reads (21%) | catalogued as rs1218897944, COSV61985955; called by muse, mutect2, varscan2
- USP42 | c.2184C>T p.G728= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV60363580; called by muse, mutect2, varscan2
- UVRAG | c.1935A>T p.S645= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV62108943; called by muse, mutect2, varscan2
- CAPN3 | c.380-316G>T | Intron (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58825471; called by muse, mutect2, varscan2
